Somatic mutation profile of tumor specimen TCGA-CV-7424-01A (aliquot TCGA-CV-7424-01A-11D-2078-08) from TCGA case TCGA-CV-7424, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 67.8 years (24,775 days).
Specimen TCGA-CV-7424-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81f2c502-4e99-480c-b13f-ed65f083f442.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7424-10A (Blood Derived Normal), aliquot TCGA-CV-7424-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/801a5cb3-c356-4148-b770-c4db81316d52

The open-access MAF lists 204 somatic variants for this specimen: 151 protein-altering or splice-affecting, 50 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 50, Nonsense Mutation 14, Frame Shift Ins 3, RNA 3, Frame Shift Del 2, Translation Start Site 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KCNQ3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749205120, COSV101196319, COSV66465699; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 6/63 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.3655A>G p.K1219E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100623293; called by mutect2, varscan2
- ACADM | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100273510; called by muse, mutect2, varscan2
- ADD1 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99296738, COSV99296976; called by muse, mutect2, varscan2
- ADGRV1 | c.1309C>G p.R437G | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101316490; called by muse, mutect2, varscan2
- AGAP3 | c.949G>A p.E317K (on ENST00000622464; = p.E353K on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as rs1255792079, COSV100103932; called by muse, mutect2, varscan2
- AJUBA | c.321dup p.D108Rfs*16 | Frame Shift Ins (INS) | VAF 10/15 reads (67%) | catalogued as rs1489088433; called by mutect2, varscan2
- AKAP12 | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs761711528, COSV99484400; called by muse, mutect2, varscan2
- ALMS1 | c.4636G>C p.E1546Q | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.131); catalogued as COSV100043676; called by muse, mutect2, varscan2
- ANK1 | c.4369C>T p.R1457C | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs778172143, COSV99225204; called by muse, mutect2
- BMS1 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs574980010, COSV65733044; called by muse, mutect2, varscan2
- BPIFA3 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0.373); catalogued as COSV100967125; called by muse, mutect2, varscan2
- C10orf82 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV100980160; called by muse, mutect2, varscan2
- C2CD3 | c.4250C>T p.P1417L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100487403; called by muse, mutect2, varscan2
- CARD6 | c.2821C>G p.Q941E | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as COSV99621292; called by muse, mutect2, varscan2
- CCT6A | c.1520C>G p.S507C | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV99303751; called by muse, mutect2, varscan2
- CHST4 | c.888G>T p.L296F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477712215, COSV100632949, COSV58296475; called by muse, mutect2, varscan2
- CLINT1 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV99754693; called by muse, mutect2, varscan2
- CLK1 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs746571339, COSV58432221; called by muse, mutect2
- CMTR2 | c.867C>A p.Y289* | Nonsense Mutation (SNP) | VAF 9/103 reads (9%) | catalogued as COSV100579346; called by muse, mutect2
- CNTNAP5 | c.2231G>T p.W744L | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV101444203; called by muse, mutect2, varscan2
- CNTRL | c.4055C>T p.S1352L | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0.028); catalogued as rs574338866, COSV99443806; called by muse, mutect2, varscan2
- COL14A1 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV52867728, COSV99920657; called by muse, mutect2, varscan2
- CPLANE1 | c.7921A>G p.T2641A | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV99951718; called by muse, mutect2, varscan2
- CTBP1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52074899; called by muse, mutect2
- CTBP1 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99338154; called by muse, mutect2
- CUX1 | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52891670; called by muse, mutect2, varscan2
- CYP7A1 | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100052636; called by muse, mutect2, varscan2
- DAB2IP | c.3073dup p.H1025Pfs*4 (on ENST00000408936; = p.H997Pfs*4 on NM_032552.3) | Frame Shift Ins (INS) | VAF 10/16 reads (63%) | catalogued as rs751187768; called by mutect2, varscan2
- DCTN1 | c.2747G>C p.R916P | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.242); catalogued as COSV100721081; called by muse, mutect2, varscan2
- DMD | c.6254G>A p.W2085* | Nonsense Mutation (SNP) | VAF 33/63 reads (52%) | catalogued as COSV100822698; called by muse, mutect2, varscan2
- DNAH5 | c.11455+1G>T p.X3819_splice | Splice Site (SNP) | VAF 26/122 reads (21%) | catalogued as COSV99454055; called by muse, mutect2, varscan2
- DNAH5 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs980507234, COSV54211470; called by muse, mutect2, varscan2
- DNAH7 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100416718; called by muse, mutect2, varscan2
- EPHA6 | c.846T>A p.F282L | Missense Mutation (SNP) | VAF 60/574 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101065408; called by muse, mutect2
- EPM2AIP1 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV51625713, COSV99212665; called by muse, mutect2
- EPS15L1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV99933681; called by muse, mutect2, varscan2
- ETV5 | c.1127C>T p.T376I | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60499500; called by muse, mutect2, varscan2
- FAM13C | c.1549C>A p.H517N | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV99514582; called by muse, mutect2
- FAM98B | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101131707; called by mutect2, varscan2
- FBXO10 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99447244; called by muse, mutect2, varscan2
- FBXO25 | c.196A>T p.K66* (on ENST00000382824 / NM_183421.2; = p.K15N on NM_012173.3) | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99367050; called by muse, mutect2, varscan2
- FLRT3 | c.1487G>C p.C496S | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99443063; called by muse, mutect2, varscan2
- FLT1 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs137937570; called by muse, mutect2, varscan2
- GSK3B | c.442C>G p.R148G | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV99955046, COSV99955599; called by muse, mutect2
- GSTCD | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV64735696; called by muse, mutect2, varscan2
- HIPK1 | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV100479656; called by muse, mutect2, varscan2
- HK1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs777012229, COSV100067948; called by muse, mutect2, varscan2
- HOXD13 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV101184343; called by muse, mutect2, varscan2
- HOXD4 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs1217619346, COSV100107038; called by muse, mutect2
- HSD17B13 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100143331; called by muse, mutect2
- ICE1 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV99665679; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1554T>G p.I518M | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as COSV100150429; called by muse, mutect2, varscan2
- ING5 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as COSV57979594; called by muse, mutect2
- ITGA2B | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.633); catalogued as CD104020, COSV99289255; called by muse, mutect2
- JUP | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs397517298, COSV100159478; ClinVar: uncertain significance; called by muse, mutect2
- KAT7 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV99372076; called by muse, mutect2, varscan2
- KLHDC7A | c.1516G>A p.G506S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as rs763581597, COSV101272850; called by muse, mutect2, varscan2
- KLHL22 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as COSV100186252; called by muse, mutect2, varscan2
- LAMA5 | c.10586G>C p.G3529A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as rs1488696782, COSV99442228; called by muse, mutect2, varscan2
- LRGUK | c.2396G>A p.R799K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99604672; called by muse, mutect2
- LRP1B | c.2527C>T p.H843Y | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs867771774, COSV100796641; called by muse, mutect2, varscan2
- LRP4 | c.3034G>A p.G1012S | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1424972529, COSV101066877; called by muse, mutect2
- LRRC4C | c.1200A>T p.K400N | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV99536571, COSV99539697; called by muse, mutect2, varscan2
- LTB4R | c.470C>G p.T157R | Missense Mutation (SNP) | VAF 74/115 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV99351161; called by muse, mutect2, varscan2
- MAGEC1 | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 185/334 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); catalogued as COSV99596491; called by muse, mutect2, varscan2
- MDN1 | c.3451G>A p.D1151N | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101021817; called by muse, mutect2, varscan2
- MTMR4 | c.1444A>G p.K482E | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV100051430; called by muse, mutect2
- MUC16 | c.39659G>C p.R13220T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV101110085; called by muse, mutect2, varscan2
- NAV3 | c.4175G>A p.G1392D | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV57083057; called by muse, mutect2, varscan2
- NLRP3 | c.1679T>G p.L560R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100276632; called by muse, mutect2, varscan2
- NPHP3 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV100447367; called by muse, mutect2, varscan2
- NR2F2 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as COSV67683325; called by muse, mutect2
- NYAP2 | c.1331G>T p.R444M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99798443; called by muse, mutect2, varscan2
- OR10W1 | c.673C>A p.R225S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101223793; called by muse, mutect2
- OR4E2 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as rs370388172, COSV57731422; called by muse, mutect2, varscan2
- OR4N2 | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 141/860 reads (16%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.774); catalogued as COSV100269987; called by muse, varscan2
- OR51B2 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100173525; called by muse, mutect2, varscan2
- OR5L1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372180673; called by muse, mutect2, varscan2
- OTOL1 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60007217, COSV60007969; called by muse, mutect2, varscan2
- PCDHB12 | c.1715G>T p.C572F | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV99507815; called by muse, varscan2
- PDE10A | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV100605760; called by muse, mutect2, varscan2
- PDS5B | c.730G>C p.G244R | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100221504; called by muse, mutect2, varscan2
- PHF3 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV100013965; called by muse, mutect2, varscan2
- PI4KB | c.1634G>A p.R545K (on ENST00000368873 / NM_001369623.1; = p.R557K on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as COSV99650147; called by muse, mutect2, varscan2
- PIK3CA | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV55924765; called by muse, mutect2, varscan2
- PLEKHA6 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs771389862, COSV99692742; called by muse, mutect2, varscan2
- PNLIPRP2 | c.977T>C p.M326T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100077985; called by muse, mutect2
- POTEM | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV101304573; called by muse, mutect2, varscan2
- PRDM9 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV99691231; called by mutect2, varscan2
- PREX2 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs745857499, COSV55763982, COSV55794214; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCB | c.1785A>T p.K595N | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV100335366; called by muse, mutect2
- PRLR | c.652T>G p.W218G | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99184767; called by muse, mutect2, varscan2
- PTCD3 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV54483792; called by muse, mutect2, varscan2
- PTCH1 | c.833G>A p.W278* | Nonsense Mutation (SNP) | VAF 46/87 reads (53%) | catalogued as CM066204, COSV59482065; called by muse, mutect2, varscan2
- R3HDM2 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100715576; called by muse, mutect2, varscan2
- RALGAPB | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99485786; called by muse, mutect2, varscan2
- RANBP2 | c.8301G>C p.Q2767H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99313223; called by muse, mutect2, varscan2
- REG3A | c.164T>A p.F55Y | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV59409360; called by muse, varscan2
- SDCCAG8 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.157); catalogued as COSV59420118; called by muse, mutect2, varscan2
- SH3RF1 | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.168); catalogued as COSV99499495; called by muse, mutect2, varscan2
- SI | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs747345955, COSV100017133; called by muse, mutect2
- SKIL | c.1102G>C p.D368H | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99378541; called by muse, mutect2
- SLC39A11 | c.847G>T p.A283S (on ENST00000542342 / NM_001159770.2; = p.A276S on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); catalogued as COSV99723984; called by muse, mutect2, varscan2
- SLC44A1 | c.410C>G p.S137* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV101029635; called by muse, mutect2, varscan2
- SLC4A2 | c.3041T>A p.I1014N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99879976; called by muse, mutect2, varscan2
- SLC9A9 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 14/136 reads (10%) | catalogued as COSV100343034, COSV57220846; called by muse, mutect2
- SLCO1C1 | c.1931G>A p.G644E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99859970; called by muse, varscan2
- SLFN5 | c.2533G>A p.V845I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100249817; called by mutect2, varscan2
- SPTA1 | c.4580C>A p.S1527Y | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63754827; called by muse, mutect2, varscan2
- STX17 | c.99A>C p.R33S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99408150; called by muse, mutect2, varscan2
- SUSD2 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546807667, COSV100844412, COSV64203818; called by muse, mutect2, varscan2
- TAF1L | c.5393C>T p.S1798F | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1351793229, COSV99645392; called by muse, mutect2, varscan2
- TDRKH | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as COSV100918031; called by muse, mutect2, varscan2
- TENT4A | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 39/205 reads (19%) | catalogued as COSV100049280; called by muse, mutect2, varscan2
- TPR | c.4016A>G p.N1339S | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100824245; called by muse, mutect2, varscan2
- TPRX1 | c.830G>A p.G277D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100445891; called by muse, mutect2, varscan2
- TRIM43 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV55528322, COSV99720111; called by muse, mutect2, varscan2
- TRIP11 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV50924813, COSV99971167; called by muse, mutect2, varscan2
- TSHR | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs374530434; called by muse, mutect2, varscan2
- TSKS | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55875199, COSV99883688; called by muse, mutect2, varscan2
- TUBA3C | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101262840, COSV67138997; called by muse, mutect2, varscan2
- UBE2O | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 92/252 reads (37%) | catalogued as COSV100085033; called by muse, mutect2, varscan2
- UTS2R | c.944A>G p.Y315C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100493399; called by muse, mutect2, varscan2
- VCAN | c.4145A>T p.D1382V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV99427249; called by muse, mutect2, varscan2
- VN1R4 | c.591G>T p.W197C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as COSV100237590; called by muse, mutect2, varscan2
- VSTM4 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1564585153, COSV60524362; called by mutect2, varscan2
- WDR70 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1474602507, COSV99457054; called by muse, mutect2, varscan2
- WNK2 | c.3025C>T p.L1009F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.942); catalogued as COSV99944516; called by muse, mutect2, varscan2
- ZFP37 | c.69A>C p.E23D | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV100953331; called by muse, mutect2, varscan2
- ZMYM4 | c.4282C>T p.P1428S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV100111121; called by muse, mutect2, varscan2
- ZNF208 | c.66C>A p.D22E | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV101237202; called by muse, mutect2, varscan2
- ZNF282 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV50483724; called by muse, mutect2, varscan2
- ZNF423 | c.3025G>A p.E1009K (on ENST00000563137 / NM_001379286.1; = p.E1001K on NM_015069.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV99283711; called by muse, mutect2, varscan2
- ZNF438 | c.1241G>C p.R414T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV100062719; called by muse, mutect2, varscan2
- ZNF521 | c.3358C>T p.Q1120* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100833381; called by muse, mutect2, varscan2
- ZNF610 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs149251185; called by muse, mutect2, varscan2
- ZNF616 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100348609, COSV57510496; called by muse, mutect2
- ZNF646 | c.3241T>G p.C1081G | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99762657; called by muse, mutect2, varscan2
- ZNF681 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV101267577; called by muse, mutect2, varscan2
- ZNRF4 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV55776052, COSV99706721; called by muse, mutect2, varscan2
- BACH1 | c.1563_1566delinsGAA p.C522Kfs*3 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by pindel, varscan2*
- BCL11A | c.1081C>T p.H361Y (on ENST00000335712 / NM_001365609.1; = p.H395Y on NM_018014.4) | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- HIVEP1 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRP8 | c.439_440insT p.R147Lfs*14 | Frame Shift Ins (INS) | VAF 11/45 reads (24%) | called by mutect2, pindel*, varscan2
- MFSD9 | c.611G>T p.C204F | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TTF1 | c.2657_2668del p.P886_A889del | In Frame Del (DEL) | VAF 16/33 reads (48%) | called by mutect2, pindel, varscan2
- ZNF804A | c.1795del p.R599Efs*46 | Frame Shift Del (DEL) | VAF 12/96 reads (13%) | called by mutect2, pindel, varscan2
- ADGRL4 | c.1920C>T p.H640= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs367751734; called by muse, mutect2, varscan2
- ADPRM | c.588G>A p.L196= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV101126103, COSV65755160; called by muse, mutect2, varscan2
- AHNAK2 | c.4941C>T p.A1647= | Silent (SNP) | VAF 173/320 reads (54%) | catalogued as rs370540872; called by muse, mutect2
- ANKRD30A | c.1209T>G p.S403= (on ENST00000611781; = p.S347= on NM_052997.2) | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV100654427; called by muse, mutect2, varscan2
- APOB | c.13605C>A p.I4535= | Silent (SNP) | VAF 64/170 reads (38%) | catalogued as COSV99267981; called by muse, mutect2, varscan2
- BANK1 | c.2193A>G p.P731= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100536840; called by muse, mutect2, varscan2
- BRMS1 | c.249G>T p.L83= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100240381; called by muse, mutect2, varscan2
- C5AR2 | c.384C>G p.L128= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as COSV99953893; called by muse, mutect2, varscan2
- CDH8 | c.1933C>A p.R645= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV54849328, COSV54870356; called by muse, mutect2, varscan2
- CENPA | c.422G>A p.*141= | Silent (SNP) | VAF 81/225 reads (36%) | catalogued as COSV99273272; called by muse, mutect2, varscan2
- COL12A1 | c.2970T>C p.D990= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV100486487; called by muse, mutect2
- COL22A1 | c.2991C>T p.L997= | Silent (SNP) | VAF 25/201 reads (12%) | catalogued as COSV100280733; called by muse, mutect2, varscan2
- DEFB112 | c.81C>T p.I27= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100452190; called by muse, mutect2, varscan2
- DNM3 | c.2280C>T p.D760= (on ENST00000355305 / NM_001350206.2; = p.D754= on NM_015569.5) | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100798636; called by muse, mutect2
- FCER2 | c.891G>T p.A297= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100689641; called by muse, mutect2, varscan2
- FDXR | c.1158G>T p.R386= (on ENST00000293195 / NM_024417.5; = p.R392= on NM_004110.6) | Silent (SNP) | VAF 52/210 reads (25%) | catalogued as COSV99501436; called by muse, mutect2, varscan2
- FGF23 | c.549C>T p.D183= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs369808475; called by muse, mutect2, varscan2
- GAD2 | c.1491G>A p.G497= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99394018; called by muse, mutect2, varscan2
- GRM8 | c.1947C>T p.S649= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV58808944; called by muse, mutect2
- IGSF5 | c.513C>T p.L171= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV101012138; called by muse, mutect2, varscan2
- ITGB5 | c.894C>T p.G298= | Silent (SNP) | VAF 4/67 reads (6%) | catalogued as COSV99951072; called by muse, mutect2
- LOXL2 | c.1188A>C p.T396= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV101207986; called by muse, mutect2, varscan2
- METAP1D | c.81C>T p.Y27= | Silent (SNP) | VAF 15/218 reads (7%) | catalogued as rs1485795405, COSV100250127; called by muse, mutect2
- MON1B | c.789G>T p.A263= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99941851; called by muse, mutect2, varscan2
- MUC16 | c.22290A>G p.Q7430= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV101201583; called by muse, mutect2, varscan2
- MYH1 | c.1578C>G p.L526= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as COSV99874734; called by muse, mutect2, varscan2
- MYT1L | c.3213G>A p.K1071= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as COSV67704859; called by muse, mutect2, varscan2
- NKX3-2 | c.225C>T p.A75= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV101219986; called by muse, mutect2, varscan2
- OGDHL | c.2340G>A p.A780= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs771265292, COSV65102561; called by muse, mutect2, varscan2
- OR13A1 | c.108G>A p.S36= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100980974, COSV65573108, COSV65573571; called by muse, mutect2, varscan2
- OR2T4 | c.720C>A p.L240= | Silent (SNP) | VAF 60/195 reads (31%) | catalogued as COSV100822615; called by muse, mutect2, varscan2
- OR2W1 | c.558G>A p.K186= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as COSV101013943; called by muse, mutect2, varscan2
- OR5R1 | c.567C>T p.C189= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100393585; called by muse, mutect2, varscan2
- P2RX7 | c.1524C>T p.T508= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- PCDHA11 | c.1683G>A p.A561= | Silent (SNP) | VAF 36/155 reads (23%) | catalogued as COSV56537339; called by muse, mutect2, varscan2
- PLOD2 | c.810C>A p.P270= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99283314; called by muse, mutect2
- PRDM9 | c.1380C>A p.S460= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV57012357, COSV57015131; called by mutect2, varscan2
- RFPL4B | c.660T>C p.F220= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV101480726; called by muse, mutect2, varscan2
- RGS21 | c.243T>C p.D81= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs1442122600, COSV101314085; called by muse, mutect2, varscan2
- RTN3 | c.2667C>T p.V889= (on ENST00000377819 / NM_001265589.2; = p.V93= on NM_006054.4) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1221707018, COSV100380340; called by muse, mutect2, varscan2
- RYR2 | c.2232A>G p.P744= | Silent (SNP) | VAF 87/315 reads (28%) | catalogued as COSV100772847; called by muse, mutect2, varscan2
- SCLT1 | c.810G>A p.E270= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs1416875114, COSV99828487; called by muse, mutect2, varscan2
- SI | c.1461A>C p.A487= | Silent (SNP) | VAF 73/161 reads (45%) | catalogued as COSV100017132, COSV52300421; called by muse, mutect2, varscan2
- SYTL2 | c.345C>T p.G115= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as rs752594764, COSV100314969; called by muse, mutect2, varscan2
- TAF6 | c.84C>T p.I28= | Silent (SNP) | VAF 24/180 reads (13%) | catalogued as rs957139683, COSV59840383; called by muse, mutect2, varscan2
- TTC23L | c.450G>A p.T150= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs755723416, COSV72205868; called by muse, mutect2, varscan2
- WDR54 | c.600A>T p.P200= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV99269935; called by muse, mutect2, varscan2
- XDH | c.2874G>A p.Q958= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV101052463; called by muse, mutect2, varscan2
- ZNF527 | c.1728C>T p.H576= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs749345375, COSV100648717; called by muse, mutect2, varscan2
- ZNF835 | c.1485G>A p.T495= | Silent (SNP) | VAF 69/212 reads (33%) | catalogued as COSV73379307; called by muse, mutect2, varscan2
- GLRXP3 | n.207G>T | RNA (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- IGKV1-13 | n.50T>C | RNA (SNP) | VAF 53/142 reads (37%) | called by muse, mutect2, varscan2
- TUBB7P | n.653C>A | RNA (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
